CCDI case PBCEHY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Peripheral nerves and autonomic nervous system.
https://portal.gdc.cancer.gov/cases/74bd2090-1afb-4c72-be38-0145a77c3d88

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Plasmacytoma, extramedullary: ICD-O-3 morphology code: 9734/3; Tissue or organ of origin: Cauda equina; Age at diagnosis: 16.2 years (5,902 days).

Biospecimens (3 samples)
- Sample 0DPYD9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPYDZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPYE6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
